Somatic mutation profile of cancer-model specimen HCM-CSHL-0801-C56-85B (3D Organoid, passage 8; aliquot HCM-CSHL-0801-C56-85B-01D-A88G-36), derived from the primary tumor of HCMI case HCM-CSHL-0801-C56, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIB.
Specimen HCM-CSHL-0801-C56-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 8.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9d0e77c1-90ea-4eb1-b816-b18519e2c762.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0801-C56-10A (Blood Derived Normal), aliquot HCM-CSHL-0801-C56-10A-01D-A88G-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ebb571db-d2b1-483d-a3e4-001ed5c592af

The open-access MAF lists 170 somatic variants for this specimen: 115 protein-altering or splice-affecting, 42 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 101, Silent 42, Nonsense Mutation 8, Intron 4, 3'UTR 4, Frame Shift Del 2, RNA 2, Frame Shift Ins 2, 5'UTR 1, 5'Flank 1, In Frame Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HPRT1 | c.529G>T p.D177Y | Missense Mutation (SNP) | VAF 108/215 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs137852492, CM900137; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 69/151 reads (46%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABHD2 | c.877C>T p.R293W | Missense Mutation (SNP) | VAF 174/387 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as rs924775630; called by muse, mutect2, varscan2
- ADAM29 | c.2409G>C p.Q803H | Missense Mutation (SNP) | VAF 203/525 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.265); catalogued as rs749271503, COSV63663923; called by muse, mutect2
- ALDH3B2 | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 176/400 reads (44%) | SIFT tolerated (0.27); PolyPhen benign (0.12); catalogued as rs768999361; called by muse, mutect2, varscan2
- ATG10 | c.531G>T p.K177N | Missense Mutation (SNP) | VAF 77/142 reads (54%) | SIFT tolerated (0.1); PolyPhen benign (0.08); catalogued as rs1203130917, COSV56425658, COSV99967213; called by muse, mutect2, varscan2
- ATN1 | c.2560C>G p.L854V | Missense Mutation (SNP) | VAF 212/447 reads (47%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.285); catalogued as COSV63110961; called by muse, mutect2, varscan2
- BAHCC1 | c.4453C>T p.R1485W | Missense Mutation (SNP) | VAF 251/851 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100311616; called by muse, mutect2, varscan2
- BRPF1 | c.2482G>C p.E828Q | Missense Mutation (SNP) | VAF 30/662 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV57403238; called by muse, mutect2
- C1orf127 | c.1804G>A p.E602K | Missense Mutation (SNP) | VAF 236/524 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.116); catalogued as COSV100983518, COSV65436208; called by muse, mutect2, varscan2
- CASS4 | c.1262C>A p.S421Y | Missense Mutation (SNP) | VAF 213/625 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.595); catalogued as rs965559493; called by muse, mutect2, varscan2
- CC2D2A | c.4787C>G p.A1596G | Missense Mutation (SNP) | VAF 103/473 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749398663; called by muse, mutect2, varscan2
- CDH23 | c.6805G>C p.E2269Q | Missense Mutation (SNP) | VAF 109/234 reads (47%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.812); catalogued as rs1258554701; called by muse, mutect2, varscan2
- CENPB | c.565C>T p.Q189* | Nonsense Mutation (SNP) | VAF 354/700 reads (51%) | catalogued as rs867023076, COSV100713651; called by muse, mutect2, varscan2
- CLEC4D | c.520C>T p.P174S | Missense Mutation (SNP) | VAF 66/128 reads (52%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.592); catalogued as COSV100223165; called by muse, mutect2, varscan2
- DENND5B | c.158G>C p.R53T | Missense Mutation (SNP) | VAF 78/182 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100172086, COSV60908914; called by muse, mutect2
- DNAH5 | c.8174C>G p.S2725C | Missense Mutation (SNP) | VAF 166/524 reads (32%) | SIFT tolerated (0.86); PolyPhen benign (0.007); catalogued as rs764288193; called by muse, mutect2, varscan2
- DUS3L | c.56G>C p.G19A | Missense Mutation (SNP) | VAF 273/556 reads (49%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.003); catalogued as rs757677248; called by muse, varscan2
- FASN | c.4427A>G p.N1476S | Missense Mutation (SNP) | VAF 205/619 reads (33%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs1317008880; called by muse, mutect2, varscan2
- FHL1 | c.880C>G p.R294G | Missense Mutation (SNP) | VAF 191/392 reads (49%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.726); catalogued as rs1219254629; called by muse, mutect2, varscan2
- FMO1 | c.913G>C p.E305Q | Missense Mutation (SNP) | VAF 139/273 reads (51%) | SIFT deleterious (0.05); PolyPhen benign (0.249); catalogued as COSV100707977, COSV100708035; called by muse, mutect2, varscan2
- FOXM1 | c.777G>C p.L259F | Missense Mutation (SNP) | VAF 217/451 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100700827; called by muse, mutect2, varscan2
- FSCB | c.1022C>G p.S341C | Missense Mutation (SNP) | VAF 241/483 reads (50%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.85); catalogued as rs1471003838; called by muse, mutect2, varscan2
- HID1 | c.244G>C p.E82Q | Missense Mutation (SNP) | VAF 185/587 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.068); catalogued as COSV100586089; called by muse, mutect2, varscan2
- HSD17B4 | c.1942C>A p.Q648K (on ENST00000414835 / NM_001199291.3; = p.Q623K on NM_000414.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 108/214 reads (50%) | SIFT tolerated (0.44); PolyPhen benign (0.039); catalogued as COSV56335854; called by muse, varscan2
- IL1RL2 | c.580G>A p.A194T | Missense Mutation (SNP) | VAF 171/363 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs142080534, COSV51818653; called by muse, mutect2, varscan2
- KDM1B | c.2210C>T p.T737M (on ENST00000449850; = p.T504M on NM_153042.4) | Missense Mutation (SNP) | VAF 373/510 reads (73%) | SIFT deleterious (0.02); PolyPhen benign (0.347); catalogued as rs200223055; called by muse, mutect2, varscan2
- KRT24 | c.997G>C p.E333Q | Missense Mutation (SNP) | VAF 169/347 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52881225; called by muse, mutect2, varscan2
- LATS2 | c.472C>A p.P158T | Missense Mutation (SNP) | VAF 177/336 reads (53%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.573); catalogued as COSV101231524; called by muse, mutect2, varscan2
- LRRC4B | c.610G>A p.E204K | Missense Mutation (SNP) | VAF 239/472 reads (51%) | SIFT tolerated (0.17); PolyPhen benign (0.094); catalogued as COSV100976050; called by muse, mutect2, varscan2
- MAGED1 | c.842C>T p.P281L | Missense Mutation (SNP) | VAF 397/763 reads (52%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.997); catalogued as rs782579183; called by muse, mutect2, varscan2
- MBD3L3 | c.527G>A p.R176Q | Missense Mutation (SNP) | VAF 174/1334 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.04); catalogued as rs1326889385, COSV61589343; called by muse, varscan2
- MDN1 | c.71G>T p.R24L | Missense Mutation (SNP) | VAF 146/340 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.191); catalogued as rs1413960592; called by muse, mutect2, varscan2
- MGA | c.5333C>G p.S1778* (on ENST00000219905 / NM_001164273.1; = p.S1569* on NM_001080541.2) | Nonsense Mutation (SNP) | VAF 175/382 reads (46%) | catalogued as COSV54948793; called by muse, mutect2, varscan2
- MYO15A | c.3482C>A p.A1161E | Missense Mutation (SNP) | VAF 21/583 reads (4%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.224); catalogued as COSV99233129; called by muse, mutect2
- NCBP3 | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 84/182 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.225); catalogued as rs1464020250; called by muse, mutect2, varscan2
- NDRG4 | c.68G>A p.R23Q (on ENST00000570248 / NM_001378344.1; = p.R55Q on NM_020465.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 308/663 reads (46%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.789); catalogued as rs148884288; called by muse, mutect2, varscan2
- NF1 | c.5797G>A p.G1933R (on ENST00000358273 / NM_001042492.3; = p.G1912R on NM_000267.3) | Missense Mutation (SNP) | VAF 90/187 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100648590; called by muse, mutect2, varscan2
- NMUR1 | c.1009G>A p.V337M | Missense Mutation (SNP) | VAF 257/581 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs1236952358; called by muse, mutect2, varscan2
- NPHS1 | c.2854C>G p.L952V | Missense Mutation (SNP) | VAF 334/693 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62288329; called by muse, mutect2, varscan2
- PCDH12 | c.3364G>T p.E1122* | Nonsense Mutation (SNP) | VAF 291/584 reads (50%) | catalogued as COSV51521367; called by muse, varscan2
- PDSS2 | c.867G>A p.M289I | Missense Mutation (SNP) | VAF 108/230 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0.011); catalogued as COSV64652985; called by muse, mutect2, varscan2
- PIP5K1B | c.1246G>A p.A416T | Missense Mutation (SNP) | VAF 156/341 reads (46%) | SIFT tolerated (0.05); PolyPhen benign (0.017); catalogued as rs764194229; called by muse, mutect2
- PREX2 | c.64C>T p.R22C | Missense Mutation (SNP) | VAF 323/1020 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55749568; called by muse, mutect2, varscan2
- ROBO2 | c.4025G>A p.G1342E | Missense Mutation (SNP) | VAF 187/397 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100167269; called by muse, mutect2, varscan2
- ROR1 | c.211C>G p.L71V | Missense Mutation (SNP) | VAF 158/300 reads (53%) | SIFT tolerated (0.33); PolyPhen benign (0.026); catalogued as rs778558577; called by muse, mutect2, varscan2
- SELENOH | c.256C>T p.P86S | Missense Mutation (SNP) | VAF 190/409 reads (46%) | SIFT tolerated (0.42); PolyPhen benign (0.021); catalogued as rs1362016588; called by muse, mutect2, varscan2
- SLC18A3 | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 42/858 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.063); catalogued as rs765344370; called by muse, mutect2
- STXBP2 | c.1240C>T p.R414W | Missense Mutation (SNP) | VAF 189/377 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs113305305; called by muse, mutect2, varscan2
- TEX15 | c.688G>A p.E230K (on ENST00000256246; = p.E613K on NM_001350162.2) | Missense Mutation (SNP) | VAF 82/178 reads (46%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as rs555117933; called by muse, mutect2, varscan2
- TMEM67 | c.1148C>G p.S383C | Missense Mutation (SNP) | VAF 49/119 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as COSV60035414, COSV60039207; called by muse, mutect2, varscan2
- TMEM67 | c.1372C>T p.Q458* | Nonsense Mutation (SNP) | VAF 100/216 reads (46%) | catalogued as rs867680226, COSV60036231; called by muse, mutect2, varscan2
- TULP4 | c.4221G>C p.E1407D | Missense Mutation (SNP) | VAF 284/558 reads (51%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.996); catalogued as COSV65578692; called by muse, mutect2, varscan2
- VPS13B | c.4746G>T p.K1582N | Missense Mutation (SNP) | VAF 124/267 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV62137871, COSV62152585; called by muse, mutect2, varscan2
- WWTR1 | c.266C>T p.S89L | Missense Mutation (SNP) | VAF 328/735 reads (45%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.968); catalogued as COSV100640934; called by muse, varscan2
- ZNF267 | c.1471C>G p.P491A | Missense Mutation (SNP) | VAF 90/172 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as COSV100339975; called by muse, mutect2, varscan2
- ZNF587B | c.1046C>T p.T349I | Missense Mutation (SNP) | VAF 172/362 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1483762618; called by muse, mutect2, varscan2
- ABCC5 | c.3098G>C p.R1033T | Missense Mutation (SNP) | VAF 144/297 reads (48%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- ACOD1 | c.194C>G p.S65C | Missense Mutation (SNP) | VAF 145/459 reads (32%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- ADAMTS19 | c.3565C>T p.Q1189* | Nonsense Mutation (SNP) | VAF 152/332 reads (46%) | called by muse, mutect2, varscan2
- ADAMTS7 | c.4448C>G p.S1483* | Nonsense Mutation (SNP) | VAF 247/507 reads (49%) | called by muse, mutect2, varscan2
- ADGB | c.3422A>T p.K1141I | Missense Mutation (SNP) | VAF 177/363 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- ADGRL1 | c.1917G>A p.M639I (on ENST00000340736 / NM_001008701.3; = p.M634I on NM_014921.5) | Missense Mutation (SNP) | VAF 40/1100 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.876); called by muse, mutect2
- AFF4 | c.1960G>A p.D654N | Missense Mutation (SNP) | VAF 128/359 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- AIFM1 | c.970C>T p.R324* | Nonsense Mutation (SNP) | VAF 119/254 reads (47%) | called by muse, mutect2, varscan2
- AMOT | c.2980C>G p.Q994E (on ENST00000371959 / NM_001113490.1; = p.Q585E on NM_133265.3) | Missense Mutation (SNP) | VAF 285/595 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.023); called by muse, varscan2
- ANAPC1 | c.1765G>T p.D589Y | Missense Mutation (SNP) | VAF 29/137 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ANKAR | c.425G>C p.R142T | Missense Mutation (SNP) | VAF 180/283 reads (64%) | SIFT deleterious (0); PolyPhen benign (0.134); called by muse, mutect2
- ARRDC1 | c.1105C>A p.P369T | Missense Mutation (SNP) | VAF 316/685 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- ART4 | c.225G>C p.E75D | Missense Mutation (SNP) | VAF 154/328 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- ATAD3A | c.697G>A p.E233K | Missense Mutation (SNP) | VAF 22/642 reads (3%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.612); called by muse, mutect2
- CLTRN | c.649G>A p.E217K | Missense Mutation (SNP) | VAF 132/265 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); called by muse, mutect2, varscan2
- CRYBG3 | c.8671G>A p.D2891N | Missense Mutation (SNP) | VAF 93/211 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0.154); called by muse, varscan2
- DOP1B | c.4195_4201dup p.R1401Pfs*22 | Frame Shift Ins (INS) | VAF 164/414 reads (40%) | called by mutect2, varscan2
- FN1 | c.616C>G p.Q206E | Missense Mutation (SNP) | VAF 178/386 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.66); called by muse, mutect2, varscan2
- GHRL | c.99G>T p.Q33H | Missense Mutation (SNP) | VAF 101/245 reads (41%) | SIFT tolerated (0.27); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- GRB7 | c.464-1G>A p.X155_splice | Splice Site (SNP) | VAF 134/1124 reads (12%) | called by muse, mutect2, varscan2
- HASPIN | c.217G>A p.G73S | Missense Mutation (SNP) | VAF 257/562 reads (46%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.68); called by muse, mutect2, varscan2
- HERC5 | c.2476G>C p.D826H | Missense Mutation (SNP) | VAF 31/136 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); called by muse, mutect2
- HPS6 | c.1365G>C p.L455F | Missense Mutation (SNP) | VAF 114/575 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- HUWE1 | c.3559G>C p.E1187Q | Missense Mutation (SNP) | VAF 219/496 reads (44%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- KLF11 | c.46G>T p.D16Y | Missense Mutation (SNP) | VAF 115/202 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- KPNA2 | c.459A>C p.E153D | Missense Mutation (SNP) | VAF 26/627 reads (4%) | SIFT tolerated (0.44); PolyPhen benign (0.001); called by muse, mutect2
- KYAT3 | c.682G>A p.E228K | Missense Mutation (SNP) | VAF 45/100 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LGI3 | c.593C>G p.A198G | Missense Mutation (SNP) | VAF 30/647 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.023); called by muse, mutect2
- MESD | c.463G>A p.D155N | Missense Mutation (SNP) | VAF 137/278 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- MLNR | c.983G>A p.R328Q | Missense Mutation (SNP) | VAF 184/382 reads (48%) | SIFT tolerated (0.38); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- NKG7 | c.281C>T p.S94L | Missense Mutation (SNP) | VAF 335/646 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- NKRF | c.897G>C p.Q299H | Missense Mutation (SNP) | VAF 243/535 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- NPHS1 | c.3017C>A p.S1006Y | Missense Mutation (SNP) | VAF 469/960 reads (49%) | SIFT tolerated (0.12); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- PARN | c.58G>C p.E20Q | Missense Mutation (SNP) | VAF 281/534 reads (53%) | SIFT tolerated (0.2); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PATL2 | c.1542dup p.S515Qfs*85 | Frame Shift Ins (INS) | VAF 194/481 reads (40%) | called by mutect2, pindel, varscan2
- PCSK5 | c.4714_4722del p.S1572_K1574del | In Frame Del (DEL) | VAF 142/560 reads (25%) | called by mutect2, pindel, varscan2
- POLR1C | c.583G>A p.D195N | Missense Mutation (SNP) | VAF 276/580 reads (48%) | SIFT tolerated (0.24); PolyPhen benign (0.344); called by muse, mutect2, varscan2
- PRICKLE3 | c.1006G>A p.D336N | Missense Mutation (SNP) | VAF 283/611 reads (46%) | SIFT deleterious (0.05); PolyPhen benign (0.413); called by muse, mutect2, varscan2
- PRUNE2 | c.3627G>C p.E1209D | Missense Mutation (SNP) | VAF 167/615 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.227); called by muse, mutect2, varscan2
- PTGS2 | c.1061A>T p.N354I | Missense Mutation (SNP) | VAF 109/236 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); called by muse, mutect2, varscan2
- PTPRN2 | c.2548G>A p.E850K | Missense Mutation (SNP) | VAF 240/240 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- RPRD1B | c.426G>C p.E142D | Missense Mutation (SNP) | VAF 243/675 reads (36%) | SIFT tolerated (0.59); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RSL1D1 | c.1309G>C p.E437Q | Missense Mutation (SNP) | VAF 29/566 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.015); called by muse, mutect2
- SAT2 | c.94del p.D32Ifs*3 | Frame Shift Del (DEL) | VAF 202/279 reads (72%) | called by mutect2, pindel, varscan2
- SEZ6L2 | c.1415G>A p.G472E (on ENST00000308713 / NM_001114099.3; = p.G402E on NM_012410.4) | Missense Mutation (SNP) | VAF 175/368 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- SLC20A1 | c.965G>C p.G322A | Missense Mutation (SNP) | VAF 278/548 reads (51%) | SIFT tolerated (0.11); PolyPhen benign (0.247); called by muse, mutect2, varscan2
- SLC25A47 | c.17G>C p.G6A | Missense Mutation (SNP) | VAF 10/352 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- SORCS1 | c.391G>A p.V131M | Missense Mutation (SNP) | VAF 303/640 reads (47%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SPATA6L | c.1103C>A p.S368Y (on ENST00000461761 / NM_001353484.2; = p.S310Y on NM_001039395.4 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 44/45 reads (98%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- STEAP4 | c.195G>C p.L65F | Missense Mutation (SNP) | VAF 186/187 reads (99%) | SIFT tolerated (0.7); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- SUSD5 | c.148C>T p.Q50* | Nonsense Mutation (SNP) | VAF 15/406 reads (4%) | called by muse, mutect2
- TAF3 | c.944C>T p.S315F | Missense Mutation (SNP) | VAF 220/455 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.467); called by muse, mutect2, varscan2
- TEX15 | c.689A>T p.E230V (on ENST00000256246; = p.E613V on NM_001350162.2) | Missense Mutation (SNP) | VAF 80/177 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.408); called by muse, mutect2, varscan2
- TSR1 | c.2240C>G p.T747S | Missense Mutation (SNP) | VAF 104/220 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- USP34 | c.9952G>C p.E3318Q | Missense Mutation (SNP) | VAF 177/355 reads (50%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- WDFY4 | c.1075G>A p.D359N | Missense Mutation (SNP) | VAF 171/427 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.374); called by muse, mutect2, varscan2
- ZAN | c.3925C>T p.P1309S | Missense Mutation (SNP) | VAF 195/195 reads (100%) | SIFT tolerated (0.22); PolyPhen benign (0.274); called by muse, mutect2, varscan2
- ZNF804A | c.2815_2818del p.R939Vfs*4 | Frame Shift Del (DEL) | VAF 91/224 reads (41%) | called by pindel, varscan2
- ABCC12 | c.3957C>T p.L1319= | Silent (SNP) | VAF 242/486 reads (50%) | catalogued as COSV100252025, COSV100253143, COSV60916041; called by muse, mutect2, varscan2
- C2CD2L | c.1062G>C p.L354= | Silent (SNP) | VAF 131/307 reads (43%) | catalogued as COSV100371265; called by muse, mutect2, varscan2
- CACNA1B | c.3549G>A p.L1183= | Silent (SNP) | VAF 168/363 reads (46%) | called by muse, mutect2, varscan2
- CCNL1 | c.81C>T p.S27= | Silent (SNP) | VAF 273/663 reads (41%) | catalogued as rs1447542676; called by muse, mutect2, varscan2
- CD82 | c.45C>G p.L15= | Silent (SNP) | VAF 127/306 reads (42%) | called by muse, mutect2, varscan2
- CDC42EP1 | c.951C>T p.L317= | Silent (SNP) | VAF 144/532 reads (27%) | catalogued as rs952768004, COSV50755715; called by muse, mutect2, varscan2
- CDRT15L2 | c.768C>T p.L256= | Silent (SNP) | VAF 192/376 reads (51%) | catalogued as rs1227350801; called by muse, mutect2, varscan2
- CEACAM20 | c.1506C>T p.P502= | Silent (SNP) | VAF 145/300 reads (48%) | called by muse, mutect2, varscan2
- CRLF3 | c.912C>T p.L304= | Silent (SNP) | VAF 18/386 reads (5%) | called by muse, mutect2
- DAND5 | c.396C>G p.L132= | Silent (SNP) | VAF 179/412 reads (43%) | catalogued as COSV100397187; called by muse, mutect2, varscan2
- DBP | c.525C>T p.L175= | Silent (SNP) | VAF 167/424 reads (39%) | catalogued as rs1162944001; called by muse, mutect2, varscan2
- DNAH3 | c.3411C>T p.A1137= | Silent (SNP) | VAF 150/396 reads (38%) | catalogued as rs778718794; called by muse, mutect2
- DYNC2I2 | c.1395C>T p.L465= | Silent (SNP) | VAF 153/342 reads (45%) | catalogued as rs1177862092; called by muse, mutect2, varscan2
- EDEM2 | c.9C>T p.F3= | Silent (SNP) | VAF 368/579 reads (64%) | catalogued as COSV65712593; called by muse, mutect2, varscan2
- EDRF1 | c.1002C>A p.V334= (on ENST00000356792 / NM_001202438.2; = p.V300= on NM_015608.2) | Silent (SNP) | VAF 152/354 reads (43%) | catalogued as COSV61762814; called by muse, mutect2, varscan2
- FAM166A | c.846C>T p.F282= | Silent (SNP) | VAF 187/407 reads (46%) | catalogued as COSV61118608; called by muse, mutect2, varscan2
- FAM169A | c.123C>A p.L41= | Silent (SNP) | VAF 65/137 reads (47%) | called by muse, mutect2, varscan2
- FBXL18 | c.204C>T p.L68= | Silent (SNP) | VAF 110/248 reads (44%) | called by muse, mutect2, varscan2
- FUZ | c.708G>A p.L236= | Silent (SNP) | VAF 215/471 reads (46%) | called by muse, mutect2, varscan2
- GJC1 | c.690C>T p.I230= | Silent (SNP) | VAF 26/618 reads (4%) | catalogued as COSV57912136; called by muse, mutect2
- GSK3A | c.267C>T p.P89= | Silent (SNP) | VAF 230/463 reads (50%) | catalogued as rs1273188378; called by muse, mutect2, varscan2
- IFIT2 | c.972G>A p.K324= | Silent (SNP) | VAF 16/232 reads (7%) | called by muse, mutect2
- KIAA1549 | c.540C>A p.V180= | Silent (SNP) | VAF 28/191 reads (15%) | called by muse, mutect2, varscan2
- LCN9 | c.147G>C p.R49= | Silent (SNP) | VAF 113/277 reads (41%) | catalogued as rs534417887; called by muse, mutect2, varscan2
- LRP2 | c.9150C>G p.V3050= | Silent (SNP) | VAF 25/653 reads (4%) | catalogued as COSV99785889; called by muse, mutect2
- LRRC15 | c.828C>G p.L276= | Silent (SNP) | VAF 39/529 reads (7%) | called by muse, mutect2
- M6PR | c.639G>A p.L213= | Silent (SNP) | VAF 212/442 reads (48%) | called by muse, mutect2, varscan2
- MYCL | c.420G>A p.P140= (on ENST00000372816 / NM_001033081.3; = p.P170= on NM_005376.5) | Silent (SNP) | VAF 24/742 reads (3%) | catalogued as rs1438270489; called by muse, mutect2
- NF1 | c.3051A>G p.Q1017= | Silent (SNP) | VAF 69/147 reads (47%) | catalogued as rs201891488, CD951796, COSV62215172; called by muse, mutect2, varscan2
- NRP2 | c.267G>A p.E89= | Silent (SNP) | VAF 158/324 reads (49%) | called by muse, mutect2, varscan2
- OR9K2 | c.759A>T p.I253= (on ENST00000305377; = p.I231= on NM_001005243.1) | Silent (SNP) | VAF 148/298 reads (50%) | catalogued as COSV59533599; called by muse, mutect2, varscan2
- PGS1 | c.693C>T p.I231= | Silent (SNP) | VAF 124/604 reads (21%) | called by muse, mutect2, varscan2
- PITPNM3 | c.336C>A p.I112= | Silent (SNP) | VAF 161/322 reads (50%) | catalogued as rs765408621; called by muse, mutect2, varscan2
- PLXNB2 | c.5079C>G p.L1693= | Silent (SNP) | VAF 148/362 reads (41%) | catalogued as rs1569156267; called by muse, mutect2, varscan2
- PSMB3 | c.516G>A p.L172= | Silent (SNP) | VAF 242/1033 reads (23%) | called by muse, mutect2, varscan2
- PTPRE | c.1518G>A p.T506= | Silent (SNP) | VAF 166/363 reads (46%) | catalogued as rs781209376; called by muse, mutect2
- RIF1 | c.2379G>A p.K793= | Silent (SNP) | VAF 50/110 reads (45%) | called by muse, mutect2, varscan2
- SPPL2B | c.1248C>G p.L416= | Silent (SNP) | VAF 164/382 reads (43%) | called by muse, mutect2, varscan2
- TG | c.5625G>A p.Q1875= | Silent (SNP) | VAF 187/417 reads (45%) | called by muse, mutect2, varscan2
- TRIM35 | c.561C>T p.I187= | Silent (SNP) | VAF 165/358 reads (46%) | called by muse, mutect2, varscan2
- UBE2C | c.231G>A p.L77= | Silent (SNP) | VAF 200/616 reads (32%) | called by muse, mutect2, varscan2
- YDJC | c.441C>T p.F147= | Silent (SNP) | VAF 286/606 reads (47%) | catalogued as rs1415280726, COSV99488927; called by muse, mutect2, varscan2
- C14orf177 | n.665G>C | RNA (SNP) | VAF 112/258 reads (43%) | called by muse, mutect2, varscan2
- C2CD6 | c.1581+1579C>G | Intron (SNP) | VAF 52/129 reads (40%) | catalogued as COSV53802792; called by muse, mutect2, varscan2
- DNAH14 | c.3052-23006G>A | Intron (SNP) | VAF 98/189 reads (52%) | called by muse, mutect2, varscan2
- EVL | c.352+9636G>A | Intron (SNP) | VAF 158/331 reads (48%) | catalogued as rs746441721; called by muse, mutect2, varscan2
- FKBP1A | c.*2042C>T | 3'UTR (SNP) | VAF 170/315 reads (54%) | called by muse, mutect2, varscan2
- LUC7L2 | c.*146T>G | 3'UTR (SNP) | VAF 137/137 reads (100%) | called by muse, mutect2, varscan2
- LUC7L2 | c.*238G>T | 3'UTR (SNP) | VAF 77/77 reads (100%) | called by muse, varscan2
- LUC7L2 | c.*244G>A | 3'UTR (SNP) | VAF 82/82 reads (100%) | called by muse, varscan2
- MT1HL1 | c.-23C>T | 5'UTR (SNP) | VAF 321/618 reads (52%) | catalogued as COSV71944888, COSV71944988; called by muse, mutect2, varscan2
- OSGIN1 | n.2054G>A | RNA (SNP) | VAF 223/470 reads (47%) | called by muse, mutect2, varscan2
- SEMA3F | chr3:50155273 C>T | 5'Flank (SNP) | VAF 36/917 reads (4%) | called by muse, mutect2
- TJP1 | c.1010+891C>T | Intron (SNP) | VAF 148/355 reads (42%) | called by muse, mutect2, varscan2
- ZFP14 | chr19:36331663 G>A | 3'Flank (SNP) | VAF 167/670 reads (25%) | called by muse, mutect2, varscan2
